Somatic mutation profile of tumor specimen C3L-02412-01 (aliquot CPT0111950009) from CPTAC case C3L-02412, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 74.0 years (27,039 days).
Specimen C3L-02412-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b4911cf-f189-45a0-9153-15f78a1e86e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02412-31 (Blood Derived Normal), aliquot CPT0112860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce99b825-b0b4-4714-a408-8f9c65de1f50

The open-access MAF lists 107 somatic variants for this specimen: 74 protein-altering or splice-affecting, 16 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 16, Intron 11, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 4, 3'UTR 3, Splice Site 1, 3'Flank 1, Splice Region 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 135/351 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSX1 | c.910_911dup p.*304Yfs*49 | Frame Shift Ins (INS) | VAF 46/92 reads (50%) | catalogued as rs515726227; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 25/222 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53982909; called by muse, mutect2, varscan2
- B4GALNT4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs746496907, COSV57327165; called by muse, mutect2, varscan2
- B4GALNT4 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs760643607; called by muse, mutect2, varscan2
- BGLAP | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 83/345 reads (24%) | catalogued as rs1239256735; called by muse, mutect2, varscan2
- BUB1 | c.1355C>A p.T452K | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241421; called by muse, mutect2, varscan2
- C11orf86 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1432069628, COSV58297004; called by muse, mutect2, varscan2
- DCC | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775848107, COSV101473552, COSV71434183; called by muse, mutect2, varscan2
- DHX16 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1161145519; called by muse, mutect2, varscan2
- EN1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 166/453 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1460623810; called by muse, mutect2, varscan2
- FRY | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 113/327 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767209890, COSV66569931; called by muse, mutect2, varscan2
- G6PD | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs781848254, COSV100855039; called by muse, mutect2, varscan2
- GOLGA4 | c.6677G>A p.R2226H | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs773081235, COSV100728796, COSV62710878; called by muse, mutect2, varscan2
- KDM4B | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs140983042; called by muse, mutect2, varscan2
- KRT74 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 84/747 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs759304994, COSV59772241; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCP1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745890489, COSV59943906; called by muse, mutect2, varscan2
- LOXHD1 | c.3161C>T p.T1054M | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs555210209, COSV56072958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K1 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 77/244 reads (32%) | catalogued as COSV68125035; called by muse, mutect2
- MDFIC | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1362372654, COSV57566700; called by muse, mutect2, varscan2
- MMD2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.475); catalogued as rs780400553, COSV101287007, COSV99065601; called by muse, mutect2, varscan2
- MYO1D | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.836); catalogued as rs199868416; called by muse, mutect2, varscan2
- NPR1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs868615410, COSV64140424; called by muse, mutect2, varscan2
- OR5B2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs369296397; called by muse, mutect2, varscan2
- PCDHA12 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 206/551 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV56496461; called by muse, mutect2, varscan2
- PCDHB12 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 189/491 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs782641715, COSV53396312; called by muse, mutect2, varscan2
- PCDHGA2 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 223/641 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as COSV53929443; called by muse, mutect2, varscan2
- PCDHGA6 | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as rs768933228, COSV53911497; called by muse, mutect2, varscan2
- PID1 | c.640G>A p.A214T (on ENST00000354069 / NM_001330156.1; = p.A212T on NM_017933.5) | Missense Mutation (SNP) | VAF 117/323 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as rs374635933; called by muse, mutect2, varscan2
- PIP4P2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs746791765, COSV53439279; called by muse, mutect2, varscan2
- PLXND1 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1366719066, COSV60710013; called by muse, mutect2
- PRAMEF14 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1283917666; called by muse, mutect2, varscan2
- PTEN | c.144del p.N48Kfs*6 | Frame Shift Del (DEL) | VAF 136/214 reads (64%) | catalogued as CM033665, COSV64308258; called by mutect2, pindel, varscan2
- RAPH1 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs776674212; called by muse, mutect2, varscan2
- RECQL4 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs750261857, COSV56742165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROCK2 | c.1900C>G p.R634G | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV55075758; called by muse, mutect2
- SCN2A | c.1526A>T p.K509I | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as CM1415068; called by muse, mutect2, varscan2
- SMG1 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.198); catalogued as rs1052925102; called by muse, mutect2, varscan2
- SMPD4 | c.591A>G p.I197M | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370147638; called by muse, mutect2, varscan2
- TBC1D25 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.988); catalogued as rs199607799; called by muse, mutect2, varscan2
- TDRD5 | c.698del p.P233Rfs*2 | Frame Shift Del (DEL) | VAF 85/173 reads (49%) | catalogued as COSV99676132; called by mutect2, pindel, varscan2
- TMEM159 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1297243394; called by muse, mutect2, varscan2
- TSPAN6 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV104426318; called by muse, mutect2, varscan2
- TSPOAP1 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs755952238, COSV52105729; called by muse, mutect2, varscan2
- ZBTB18 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 97/381 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs959583002; called by muse, mutect2, varscan2
- ACAN | c.5089T>C p.S1697P | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AIMP1 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ANKRD30B | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- APOBR | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ASCC3 | c.4516A>T p.K1506* | Nonsense Mutation (SNP) | VAF 85/226 reads (38%) | called by muse, mutect2, varscan2
- CACNA1F | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); called by muse, mutect2
- CAMSAP3 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.8267-2A>G p.X2756_splice (on ENST00000297405 / NM_001363185.1; = p.X2587_splice on NM_052900.3) | Splice Site (SNP) | VAF 67/154 reads (44%) | called by muse, mutect2, varscan2
- CTNNA3 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CUL4A | c.631C>T p.R211W (on ENST00000375440 / NM_001008895.4; = p.R111W on NM_003589.3) | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTNA | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ISL1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 84/226 reads (37%) | called by muse, mutect2, varscan2
- KAZN | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT86 | c.738G>A p.E246= | Splice Region (SNP) | VAF 204/614 reads (33%) | called by muse, mutect2, varscan2
- LHX5 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MOXD1 | c.1656G>C p.K552N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- NUP93 | c.2181_2201del p.E728_F734del | In Frame Del (DEL) | VAF 34/132 reads (26%) | called by mutect2, pindel, varscan2
- ODC1 | c.1318del p.S440Lfs*8 | Frame Shift Del (DEL) | VAF 93/298 reads (31%) | called by mutect2, pindel, varscan2
- PAPOLA | c.1336dup p.T446Nfs*5 | Frame Shift Ins (INS) | VAF 38/113 reads (34%) | called by mutect2, varscan2
- PEX6 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 205/464 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PPRC1 | c.2009del p.L670Rfs*9 | Frame Shift Del (DEL) | VAF 85/367 reads (23%) | called by mutect2, pindel, varscan2
- PTPRJ | c.3782A>G p.N1261S | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RABGEF1 | c.813T>G p.N271K (on ENST00000439720 / NM_001287061.2; = p.N258K on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAMM50 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- STX16 | c.650G>T p.G217V (on ENST00000371141 / NM_001001433.3; = p.G196V on NM_003763.6) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); called by muse, varscan2
- TFAP4 | c.453_462dup p.M155Afs*6 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | called by mutect2, varscan2
- ZNF608 | c.3702dup p.Q1235Tfs*27 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- A1BG | c.1071G>T p.A357= | Silent (SNP) | VAF 157/452 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.4605C>T p.T1535= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as rs1410729278, COSV55789261; called by muse, mutect2, varscan2
- ARHGEF17 | c.30T>A p.L10= | Silent (SNP) | VAF 82/233 reads (35%) | called by muse, mutect2, varscan2
- CLSPN | c.882G>A p.Q294= | Silent (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- CSMD1 | c.10125T>C p.T3375= (on ENST00000520002; = p.T3374= on NM_033225.6) | Silent (SNP) | VAF 60/172 reads (35%) | catalogued as rs776135074; called by muse, mutect2, varscan2
- GJB5 | c.117G>A p.T39= | Silent (SNP) | VAF 102/298 reads (34%) | catalogued as rs774856602, COSV58357117; called by muse, mutect2, varscan2
- NFE2L1 | c.2004G>A p.A668= | Silent (SNP) | VAF 31/266 reads (12%) | catalogued as rs752178202; called by muse, mutect2, varscan2
- PHRF1 | c.1434C>T p.P478= (on ENST00000264555 / NM_001286581.2; = p.P477= on NM_020901.4) | Silent (SNP) | VAF 95/185 reads (51%) | catalogued as rs780633720; called by muse, mutect2, varscan2
- PSMD3 | c.1009C>T p.L337= | Silent (SNP) | VAF 57/179 reads (32%) | called by muse, mutect2, varscan2
- RAP1GAP | c.363C>T p.I121= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs373093872, COSV99265988; called by muse, mutect2, varscan2
- RPGRIP1L | c.663G>A p.Q221= | Silent (SNP) | VAF 75/186 reads (40%) | catalogued as COSV50902785; called by muse, mutect2, varscan2
- SNTA1 | c.1485G>A p.S495= | Silent (SNP) | VAF 162/447 reads (36%) | catalogued as rs374100952; called by muse, mutect2, varscan2
- TAS2R39 | c.321C>T p.D107= | Silent (SNP) | VAF 83/213 reads (39%) | catalogued as rs565607872; called by muse, mutect2, varscan2
- TRAF7 | c.762C>T p.C254= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as rs780317358; called by muse, mutect2, varscan2
- ZFYVE16 | c.1872T>G p.P624= | Silent (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- ZNF503 | c.543C>T p.P181= | Silent (SNP) | VAF 123/509 reads (24%) | catalogued as rs888222546; called by muse, mutect2, varscan2
- AC114490.3 | c.*385G>A | 3'UTR (SNP) | VAF 43/99 reads (43%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506322 G>C | 3'Flank (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2
- C4B | c.3154+49C>T | Intron (SNP) | VAF 54/230 reads (23%) | called by muse, mutect2
- CCDC22 | c.-15C>T | 5'UTR (SNP) | VAF 147/405 reads (36%) | catalogued as rs1557112518; called by muse, mutect2, varscan2
- DGKZ | c.3137+31C>T | Intron (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-1944C>T | Intron (SNP) | VAF 93/246 reads (38%) | called by muse, mutect2, varscan2
- GALE | c.-5-23dup | Intron (INS) | VAF 103/374 reads (28%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1781-512T>C | Intron (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-101193C>T | Intron (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- LITAF | c.*308C>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+915C>T | Intron (SNP) | VAF 27/385 reads (7%) | catalogued as rs574918486; called by muse, mutect2
- MGAM | c.4619-7939_4619-7937del | Intron (DEL) | VAF 33/72 reads (46%) | catalogued as rs1285340385; called by pindel, varscan2
- PAX1 | c.917-36G>A | Intron (SNP) | VAF 193/448 reads (43%) | catalogued as rs769768726; called by muse, mutect2, varscan2
- PTGES3L | c.*11C>G | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- RCCD1 | c.950-36C>T | Intron (SNP) | VAF 133/386 reads (34%) | catalogued as rs1567169733; called by muse, mutect2
- RPS24 | c.*20-30T>G | Intron (SNP) | VAF 209/378 reads (55%) | called by muse, mutect2, varscan2
- ZNF529 | chr19:36574835 G>C | 5'Flank (SNP) | VAF 66/165 reads (40%) | called by muse, mutect2, varscan2
